Somatic mutation profile of tumor specimen C3N-00848-02 (aliquot CPT0024130009) from CPTAC case C3N-00848, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.3 years (24,214 days).
Specimen C3N-00848-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f9bf8be-ec0f-4334-9a2d-c7f8f6deaa32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00848-71 (Blood Derived Normal), aliquot CPT0024210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dc945ce-422c-49db-916d-5d7fa5da2aab

The open-access MAF lists 98 somatic variants for this specimen: 72 protein-altering or splice-affecting, 17 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 17, Intron 5, Frame Shift Del 4, RNA 2, 5'UTR 2, Splice Region 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH7A1 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780233639, CM121732, COSV63160932; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ESR1 | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 161/436 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV52782930, COSV52787207, COSV52795259; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 160/337 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 122/346 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55878215, COSV55881107, COSV55917331; called by muse, varscan2
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 46/103 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 93/362 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs533435962, COSV101182998; called by mutect2, varscan2
- BRD8 | c.2680C>A p.L894M | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV50169912; called by muse, mutect2, varscan2
- C22orf42 | c.493+5G>A | Splice Region (SNP) | VAF 65/206 reads (32%) | catalogued as rs772849724; called by muse, mutect2, varscan2
- CD300E | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.123); catalogued as rs73359250; called by muse, mutect2, varscan2
- CERS6 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 41/192 reads (21%) | catalogued as rs1173624557, COSV99986563; called by muse, mutect2, varscan2
- CFAP74 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs772880951, COSV54568613; called by muse, mutect2, varscan2
- CNNM1 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.073); catalogued as rs761279428, COSV100763989; called by muse, mutect2, varscan2
- CSF2RA | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 90/344 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV62624315; called by muse, varscan2
- DTX3 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs368232533; called by muse, mutect2, varscan2
- EBF3 | c.1228G>A p.E410K (on ENST00000355311 / NM_001375392.1; = p.E401K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); catalogued as rs1490116339; called by muse, varscan2
- FAM98C | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442170374, COSV53038873, COSV53039384; called by muse, mutect2, varscan2
- GAL3ST2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs202108971, COSV51950164; called by muse, mutect2
- GHDC | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.448); catalogued as rs376472900; called by muse, mutect2, varscan2
- GPR108 | c.1039G>A p.A347T (on ENST00000264080 / NM_001080452.1; = p.A105T on NM_020171.2) | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs758270083, COSV51185104; called by muse, mutect2, varscan2
- GRID1 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs375277319; called by muse, mutect2, varscan2
- GTPBP3 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1190192736; called by muse, mutect2
- KDM5C | c.2622+8C>T | Splice Region (SNP) | VAF 90/325 reads (28%) | catalogued as rs782457546; called by muse, mutect2, varscan2
- KMT2C | c.11057A>G p.N3686S | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1424689396; called by muse, mutect2, varscan2
- L3MBTL4 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 102/263 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as rs1307398243; called by muse, mutect2, varscan2
- LSS | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs1226189448, COSV62702744; called by muse, mutect2, varscan2
- MBD1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 128/396 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs777428957, COSV99495171; called by muse, mutect2, varscan2
- MED12 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 93/313 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV100378317; called by muse, mutect2, varscan2
- OCA2 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 97/392 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV62341550; called by muse, mutect2, varscan2
- OR7C1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756541110, COSV50183626; called by muse, mutect2, varscan2
- PCDHA4 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as rs782755918; called by muse, mutect2, varscan2
- PCSK1N | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV54432903; called by muse, mutect2, varscan2
- PIP4P2 | c.487-2A>G p.X163_splice | Splice Site (SNP) | VAF 35/118 reads (30%) | catalogued as COSV99575118; called by muse, mutect2, varscan2
- SCRN1 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs867994176, COSV54128364; called by muse, mutect2, varscan2
- SERPINB3 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs758687729; called by muse, mutect2, varscan2
- SGCE | c.1135C>T p.R379W (on ENST00000647096; = p.R343W on NM_003919.3) | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757796461, COSV99722438; called by muse, mutect2, varscan2
- SPSB1 | c.555C>G p.D185E | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60161948; called by muse, varscan2
- TAFA3 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100721487; called by muse, mutect2, varscan2
- THAP4 | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757514473; called by muse, mutect2, varscan2
- TRABD2A | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs371865663; called by muse, mutect2, varscan2
- TRAPPC12 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761567333, COSV60847897; called by muse, mutect2, varscan2
- USP35 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1418516247; called by muse, mutect2, varscan2
- VCX3A | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs749763251; called by mutect2, varscan2
- ARID1A | c.5564del p.I1855Tfs*28 | Frame Shift Del (DEL) | VAF 61/199 reads (31%) | called by mutect2, pindel, varscan2
- ASXL3 | c.2053A>C p.T685P | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- BCL7A | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- DSCAML1 | c.1476G>T p.K492N (on ENST00000321322; = p.K432N on NM_020693.4) | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- EIF2AK3 | c.2261C>T p.S754L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FBXO45 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FIGNL2 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 124/495 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- HEATR6 | c.1001A>T p.K334M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- IHH | c.819del p.A274Lfs*91 | Frame Shift Del (DEL) | VAF 89/290 reads (31%) | called by mutect2, pindel, varscan2
- LRRC41 | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MAMLD1 | c.1613C>A p.T538N | Missense Mutation (SNP) | VAF 151/501 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MSX1 | c.520_521del p.K174Afs*39 | Frame Shift Del (DEL) | VAF 30/132 reads (23%) | called by mutect2, pindel, varscan2
- PAAF1 | c.733C>G p.R245G | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- PARP4 | c.821C>G p.A274G | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PHF20L1 | c.1026G>C p.L342F | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLA2R1 | c.3658A>G p.S1220G | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PPTC7 | c.717A>C p.K239N | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PTEN | c.139_140del p.R47Efs*4 | Frame Shift Del (DEL) | VAF 104/173 reads (60%) | called by mutect2, pindel, varscan2
- RIMS1 | c.4440G>T p.K1480N | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SERPINE3 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC2A14 | c.827A>G p.E276G | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- TECRL | c.971T>G p.I324S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2
- TES | c.480C>G p.D160E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TIAM1 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TMOD3 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TMPRSS11F | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIM51GP | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 11/286 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, mutect2
- UHRF1BP1L | c.3016G>A p.D1006N | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF304 | c.1775G>A p.C592Y | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- ADGRV1 | c.3180G>A p.T1060= | Silent (SNP) | VAF 53/236 reads (22%) | catalogued as rs201516498; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BCO1 | c.393C>T p.C131= | Silent (SNP) | VAF 117/425 reads (28%) | catalogued as rs748475104, COSV50729668; called by muse, mutect2, varscan2
- CARMIL3 | c.3870C>T p.P1290= | Silent (SNP) | VAF 46/150 reads (31%) | called by muse, mutect2, varscan2
- FOXB1 | c.369C>A p.A123= | Silent (SNP) | VAF 77/247 reads (31%) | catalogued as rs1315880410; called by muse, mutect2, varscan2
- GSPT2 | c.285C>T p.G95= | Silent (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- ICA1L | c.87C>T p.V29= | Silent (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- LONRF2 | c.1218C>T p.D406= | Silent (SNP) | VAF 74/272 reads (27%) | catalogued as rs756818095, COSV66540226; called by muse, mutect2, varscan2
- MAMDC2 | c.1573C>A p.R525= | Silent (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- NLRP4 | c.1293G>A p.A431= | Silent (SNP) | VAF 68/197 reads (35%) | catalogued as rs1320712119, COSV56717029; called by muse, mutect2, varscan2
- PFKFB1 | c.1374G>A p.R458= | Silent (SNP) | VAF 56/196 reads (29%) | called by muse, mutect2, varscan2
- R3HDM2 | c.1854G>A p.S618= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as rs369575037; called by muse, mutect2
- RBP3 | c.1062G>A p.L354= | Silent (SNP) | VAF 97/538 reads (18%) | catalogued as rs201535755; called by muse, mutect2, varscan2
- SART1 | c.612C>T p.I204= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as rs371186444; called by muse, mutect2, varscan2
- STYXL2 | c.528C>T p.P176= | Silent (SNP) | VAF 104/518 reads (20%) | catalogued as rs1218860277; called by muse, mutect2, varscan2
- TFIP11 | c.588G>A p.E196= | Silent (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- VWF | c.2229C>T p.V743= | Silent (SNP) | VAF 81/399 reads (20%) | called by muse, mutect2, varscan2
- ZIC4 | c.219G>A p.A73= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs778224178, COSV67174206; called by muse, mutect2, varscan2
- AC114741.1 | n.383A>T | RNA (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- ARF5 | c.-21C>G | 5'UTR (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- C5orf17 | n.259C>A | RNA (SNP) | VAF 27/83 reads (33%) | catalogued as rs527750983; called by muse, mutect2, varscan2
- CELSR1 | c.7760-328C>T | Intron (SNP) | VAF 41/111 reads (37%) | catalogued as rs748389321; called by muse, mutect2, varscan2
- CHCHD7 | c.55-42C>T | Intron (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100374610; called by muse, varscan2
- JAKMIP2 | c.2413-3790T>A | Intron (SNP) | VAF 39/165 reads (24%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+297G>A | Intron (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2
- PTBP1 | c.1075+11G>A | Intron (SNP) | VAF 47/177 reads (27%) | catalogued as rs377512710; called by muse, mutect2, varscan2
- VKORC1 | c.-19C>G | 5'UTR (SNP) | VAF 86/309 reads (28%) | catalogued as rs775171450; called by muse, mutect2, varscan2
